Gene-level copy-number profile of tumor specimen TCGA-BB-4227-01A from TCGA case TCGA-BB-4227, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.6 years (24,322 days).
Specimen TCGA-BB-4227-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.dc985e57-caef-4c8f-adc9-92d035701c3e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-4227-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e0017731-735c-481c-b0e7-85ef7bf38220

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 13,052; copy number 2: 38,055; copy number 3: 8,070; copy number 4: 236; copy number 5: 10; copy number 6: 168; copy number 9: 37; copy number 12: 32; copy number 14: 34; copy number 15: 66.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BB-4227-01A-01D-1869-01): tumor purity 0.79, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:190,908,460–191,246,172, 10 genes (within-gene range 0–1): STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1.
- chr3:78,525,101–84,051,419, 31 genes: MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1.
- chr3:84,691,681–84,692,591, 1 gene: AC117482.1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 10 genes (within-gene range 0–2): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 347 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:29,407,100–30,008,316, 7 genes, copy number 6: AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1.
- chr9:122,120,082–122,120,167, 1 gene, copy number 5: MIR4478.
- chr11:43,921,059–44,001,157, 1 gene, copy number 5 (within-gene range 1–5): AC087521.3.
- chr11:68,460,731–68,615,334, 1 gene, copy number 14 (within-gene range 1–14): PPP6R3.
- chr11:68,612,899–71,524,107, 70 genes, copy number 9–14 (within-gene range 2–14) (broad region; genes not listed).
- chr11:101,890,674–105,101,431, 66 genes, copy number 15 (within-gene range 1–15) (broad region; genes not listed).
- chr13:73,399,031–73,408,352, 2 genes, copy number 5: AL162376.1, MARK2P12.
- chr17:39,401,793–41,047,316, 89 genes, copy number 6–12 (broad region; genes not listed).
- chr17:43,044,295–43,476,665, 35 genes, copy number 6 (within-gene range 3–6): BRCA1, RPL21P4, NBR2, AC135721.2, AC135721.1, AC060780.1, BRCA1P1, AC060780.2, NBR1, TMEM106A, CCDC200, RNU2-1, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, LINC00910, AC109326.1, RNU2-4P, RNU6-1137P, ARL4D, RNU6-470P, MIR2117HG, MIR2117, RNU6-406P, RNU6-971P, AC087650.1.
- chr17:51,260,546–57,745,299, 75 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,205. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
